Somatic mutation profile of tumor specimen TCGA-B6-A1KF-01A (aliquot TCGA-B6-A1KF-01A-11D-A13L-09) from TCGA case TCGA-B6-A1KF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.1 years (24,891 days).
Specimen TCGA-B6-A1KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c441ca78-6116-41ec-b53e-9405cf5f5314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A1KF-10A (Blood Derived Normal), aliquot TCGA-B6-A1KF-10A-01W-A14R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba43705b-8a84-4b4c-8563-14a177c0f0c5

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1del p.X125_splice | Splice Site (DEL) | VAF 24/26 reads (92%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by mutect2, varscan2
- ABI3BP | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as COSV52535017; called by muse, mutect2, varscan2
- ARHGEF2 | c.2162C>G p.S721C (on ENST00000361247 / NM_001162383.2; = p.S693C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/363 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV58110591; called by muse, mutect2, varscan2
- BAZ2B | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs763350917, COSV58599852; called by muse, mutect2, varscan2
- CACNA1F | c.4589T>A p.L1530Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59904232; called by muse, mutect2, varscan2
- CCDC189 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60311828; called by muse, mutect2, varscan2
- CFAP61 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55627730; called by muse, mutect2, varscan2
- CHAMP1 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs782768495, COSV63522287; called by muse, mutect2, varscan2
- CREBBP | c.4778C>A p.T1593N | Missense Mutation (SNP) | VAF 415/988 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52122048; called by muse, mutect2, varscan2
- DNM1 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57851127; called by muse, mutect2, varscan2
- EPC1 | c.587_588del p.Q196Rfs*10 | Frame Shift Del (DEL) | VAF 46/258 reads (18%) | catalogued as COSV53925521; called by mutect2, pindel, varscan2
- GLCE | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55945608; called by muse, mutect2, varscan2
- HECTD4 | c.2638C>A p.R880S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100296130, COSV61178958; called by muse, mutect2, varscan2
- HIP1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61185480; called by muse, mutect2, varscan2
- IKBKB | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 34/154 reads (22%) | catalogued as COSV60597127; called by muse, varscan2
- IQGAP3 | c.3347A>G p.D1116G | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV63251090; called by muse, mutect2, varscan2
- LGALS9B | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1218165682, COSV60864883; called by mutect2, varscan2
- LIFR | c.3199C>A p.Q1067K | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV54689323; called by muse, mutect2, varscan2
- MARF1 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.935); catalogued as COSV100705779; called by muse, mutect2
- METTL3 | c.1522C>G p.R508G | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52967762, COSV52968677; called by muse, mutect2, varscan2
- MYBPH | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55137988; called by muse, mutect2, varscan2
- OR2T35 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 113/467 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1394382017, COSV100442212; called by muse, mutect2, varscan2
- PCK1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60127570, COSV60127715; called by muse, mutect2, varscan2
- PGM5 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67163682; called by muse, mutect2, varscan2
- PIK3R6 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.656); catalogued as rs777141500, COSV61003588; called by muse, mutect2, varscan2
- PPIAL4A | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 92/1239 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.578); catalogued as rs1268746618; called by muse, mutect2
- RANBP6 | c.3253G>C p.E1085Q | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52389184; called by muse, mutect2, varscan2
- RTF2 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as rs1471555429, COSV50128458; called by muse, mutect2, varscan2
- RYR2 | c.5017G>T p.A1673S | Missense Mutation (SNP) | VAF 172/208 reads (83%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV63682760; called by muse, mutect2, varscan2
- RYR2 | c.5018C>T p.A1673V | Missense Mutation (SNP) | VAF 172/210 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63682767; called by muse, mutect2, varscan2
- SDHAF2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.827); catalogued as rs145616631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMG2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs144655663; called by muse, mutect2, varscan2
- TECR | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 54/61 reads (89%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs763449006, COSV53108136; called by muse, mutect2, varscan2
- TMED6 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1006937674, COSV54747942; called by muse, mutect2, varscan2
- TMEM131L | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400885033, COSV53643913; called by muse, mutect2, varscan2
- UGT3A2 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs199567567; called by muse, mutect2, varscan2
- USP32 | c.3878T>C p.I1293T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV56268135; called by muse, mutect2, varscan2
- UTP14A | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV64086744, COSV64086807; called by muse, mutect2, varscan2
- WWP1 | c.2133A>G p.R711= | Splice Region (SNP) | VAF 36/286 reads (13%) | catalogued as COSV55358804; called by muse, mutect2, varscan2
- ZNF223 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV101462623; called by muse, mutect2, varscan2
- ZNF763 | c.1022A>C p.Q341P (on ENST00000358987 / NM_001367172.2; = p.Q344P on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs751605910, COSV100676054; called by muse, mutect2, varscan2
- ARRDC3 | c.665_666dup p.V223Wfs*19 | Frame Shift Ins (INS) | VAF 42/67 reads (63%) | called by mutect2, pindel, varscan2
- RNF169 | c.1557_1565delinsT p.K519Nfs*2 | Frame Shift Del (DEL) | VAF 30/51 reads (59%) | called by pindel, varscan2*
- ARHGEF40 | c.3843C>T p.I1281= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV53879997; called by muse, mutect2, varscan2
- GPC2 | c.969G>A p.K323= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV52784696, COSV52784926; called by muse, mutect2, varscan2
- KRT77 | c.1416C>T p.G472= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs751887058, COSV59239601; called by muse, mutect2, varscan2
- MAP2K6 | c.570C>T p.L190= | Silent (SNP) | VAF 82/254 reads (32%) | catalogued as rs148709755, COSV63008077; called by muse, mutect2, varscan2
- MYO18A | c.3414T>G p.R1138= | Silent (SNP) | VAF 53/367 reads (14%) | catalogued as COSV62865433, COSV62870565; called by muse, mutect2, varscan2
- NFASC | c.1224C>T p.C408= (on ENST00000339876 / NM_001378329.1; = p.C419= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 118/563 reads (21%) | catalogued as COSV58364526; called by muse, mutect2, varscan2
- NME8 | c.894G>A p.K298= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs755364633, COSV52249671; called by muse, mutect2, varscan2
- OR2T3 | c.801G>A p.P267= | Silent (SNP) | VAF 162/805 reads (20%) | catalogued as rs370677701; called by muse, mutect2, varscan2
- SHFL | c.345C>T p.C115= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs1461127224, COSV53461438; called by muse, mutect2, varscan2
- SLC12A5 | c.243G>T p.V81= (on ENST00000454036 / NM_001134771.2; = p.V58= on NM_020708.5) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV54792783, COSV54794452; called by muse, mutect2, varscan2
- SPAM1 | c.1290T>A p.S430= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as COSV56143232; called by muse, mutect2, varscan2
- UVSSA | c.270G>A p.T90= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs747109076, COSV66229768; called by muse, varscan2
- XRN1 | c.4686C>A p.L1562= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV53811177; called by muse, mutect2, varscan2
- ZNF749 | c.933T>G p.A311= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV61945974; called by muse, mutect2, varscan2
- VPS26C | chr21:37221404 G>A | 3'Flank (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
